Somatic mutation profile of tumor specimen TCGA-EJ-7218-01B (aliquot TCGA-EJ-7218-01B-11D-A32B-08) from TCGA case TCGA-EJ-7218, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 71.7 years (26,181 days).
Specimen TCGA-EJ-7218-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be4405f8-b24a-4435-ae8d-a206ef62c3e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7218-10A (Blood Derived Normal), aliquot TCGA-EJ-7218-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d71ce69c-fd8b-417c-981f-dbf86839b202

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Nonsense Mutation 4, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCAS2 | c.174T>G p.Y58* | Nonsense Mutation (SNP) | VAF 22/231 reads (10%) | catalogued as COSV101058652; called by muse, mutect2
- CCDC15 | c.1001A>G p.D334G | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.495); catalogued as COSV100777034; called by muse, mutect2, varscan2
- COL17A1 | c.2635C>T p.R879* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as rs757548746, COSV100793283; called by muse, mutect2, varscan2
- CRYGN | c.467C>G p.S156C | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.334); catalogued as COSV100484788; called by muse, mutect2, varscan2
- DNAH11 | c.9701A>G p.K3234R | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as COSV100180169; called by muse, mutect2, varscan2
- EGF | c.332T>G p.V111G | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV99491248; called by muse, varscan2
- ERI2 | c.637C>T p.H213Y | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99184827; called by muse, mutect2
- FLG2 | c.6182C>T p.S2061L | Missense Mutation (SNP) | VAF 58/597 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV101166082; called by muse, mutect2
- HOXB13 | c.437T>C p.V146A | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV99285309; called by muse, mutect2, varscan2
- KIR2DL3 | c.152C>A p.S51* | Nonsense Mutation (SNP) | VAF 23/214 reads (11%) | catalogued as COSV60900439; called by muse, mutect2, varscan2
- LINGO2 | c.212G>T p.S71I | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as rs376001180, COSV100431021, COSV58062529; called by muse, mutect2
- LTBP3 | c.2186C>A p.A729D | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as COSV100100126; called by muse, mutect2, varscan2
- MUC17 | c.3788C>T p.A1263V | Missense Mutation (SNP) | VAF 90/396 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV100074544; called by muse, mutect2, varscan2
- RSF1 | c.1935A>C p.K645N | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV100407653; called by muse, mutect2
- SASH3 | c.898C>A p.P300T | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100795280; called by muse, mutect2
- SFSWAP | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748745315, COSV99906286; called by muse, mutect2, varscan2
- TTN | c.60281A>G p.Y20094C (on ENST00000591111; = p.Y12670C on NM_003319.4) | Missense Mutation (SNP) | VAF 7/121 reads (6%) | PolyPhen possibly damaging (0.794); catalogued as rs1430331721, COSV100623587; called by muse, mutect2
- UTP11 | c.45A>C p.E15D | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV100884974; called by muse, mutect2, varscan2
- ZBTB41 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 6/68 reads (9%) | catalogued as COSV100963358; called by muse, mutect2
- ZNFX1 | c.5669C>G p.A1890G | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100872522; called by muse, mutect2, varscan2
- DCAF12L1 | c.1380C>T p.G460= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs1345062187, COSV100948406; called by muse, mutect2
- DGCR2 | c.210C>T p.T70= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs761519423, COSV54218608, COSV99593854; called by muse, mutect2
- LCE1C | c.234C>T p.S78= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV100908468; called by muse, mutect2, varscan2
- LZTS1 | c.528G>A p.R176= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99743192; called by muse, mutect2, varscan2
- ZNF334 | c.792G>T p.P264= | Silent (SNP) | VAF 16/146 reads (11%) | catalogued as rs76419021, COSV100749163, COSV61619316; called by muse, mutect2, varscan2
- NAA80 | c.-52T>G | 5'UTR (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99807825; called by muse, mutect2, varscan2
- TTN | c.10360+2726T>G | Intron (SNP) | VAF 6/64 reads (9%) | catalogued as COSV100623590; called by muse, mutect2
